Somatic mutation profile of tumor specimen TARGET-10-PASFHR-09A (aliquot TARGET-10-PASFHR-09A-01D) from TARGET case TARGET-10-PASFHR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.6 years (5,323 days).
Specimen TARGET-10-PASFHR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4375145-388d-4521-8303-4d0fead83aad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASFHR-10A (Blood Derived Normal), aliquot TARGET-10-PASFHR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/379916b8-df31-4be8-be3c-33e184930d9d

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, Silent 2, 5'UTR 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.3401C>T p.T1134I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV59387824; called by muse, mutect2, varscan2
- ARL14EPL | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 35/96 reads (36%) | catalogued as rs981988957, COSV59948454, COSV59948566; called by muse, mutect2, varscan2
- BOD1L1 | c.7102G>A p.V2368M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV50016745; called by mutect2, varscan2
- CRACD | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as COSV51731561; called by muse, mutect2
- ERCC6 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs749392467, COSV63390859, COSV63394072; called by muse, mutect2, varscan2
- GRHL3 | c.1328C>T p.T443M (on ENST00000350501 / NM_198174.3; = p.T448M on NM_021180.3) | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.395); catalogued as rs140365190; called by muse, mutect2, varscan2
- PDIA5 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs140341357; called by muse, mutect2
- SEC24D | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV54880619; called by muse, mutect2
- SLC35C2 | c.84_85insTTACCT p.S28_I29insLP | In Frame Ins (INS) | VAF 15/37 reads (41%) | catalogued as COSV54757267; called by mutect2, pindel, varscan2
- SYPL2 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs372720702; called by muse, mutect2
- APOA5 | c.18C>T p.A6= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs199724136; called by muse, mutect2, varscan2
- CFTR | c.306G>T p.L102= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- DUSP28 | c.-24A>G | 5'UTR (SNP) | VAF 6/12 reads (50%) | catalogued as rs1487088564; called by muse, mutect2, varscan2
- NFASC | c.3019+12C>A | Intron (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- UBAP2 | c.1057-43T>C | Intron (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
